Somatic mutation profile of tumor specimen TCGA-EM-A3FP-01A (aliquot TCGA-EM-A3FP-01A-11D-A21A-08) from TCGA case TCGA-EM-A3FP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 71.6 years (26,158 days).
Specimen TCGA-EM-A3FP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33f26b7e-6f71-4065-a214-5641df551302.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3FP-10A (Blood Derived Normal), aliquot TCGA-EM-A3FP-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0dce59b-7317-489b-a556-8f75abf58bb4

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNG5 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV55361131, COSV55364883; called by muse, mutect2, varscan2
- HGD | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV52201737; called by muse, mutect2, varscan2
- INTS1 | c.5027G>C p.C1676S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV67179910; called by muse, mutect2, varscan2
- MOB4 | c.376A>G p.R126G | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV52097346; called by muse, mutect2, varscan2
- PMS1 | c.2407A>G p.S803G | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as COSV59720332; called by muse, mutect2, varscan2
- SMC3 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1488636661, COSV62422559; called by muse, mutect2, varscan2
- TBL2 | c.45G>T p.L15F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV59788485; called by muse, mutect2, varscan2
- TJP1 | c.2695T>G p.S899A | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV62046859; called by muse, mutect2, varscan2
- YLPM1 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV53121373; called by muse, mutect2, varscan2
- ZBTB22 | c.836C>A p.A279D | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV56473047; called by muse, mutect2, varscan2
- ZNF260 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV72951299; called by muse, mutect2, varscan2
- EGFL8 | c.687C>T p.A229= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs146401113; called by muse, mutect2, varscan2
